Somatic mutation profile of tumor specimen TCGA-A6-5667-01A (aliquot TCGA-A6-5667-01A-21D-1719-10) from TCGA case TCGA-A6-5667, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 40.4 years (14,756 days).
Specimen TCGA-A6-5667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 885c8d3e-fb27-45ce-9814-c5df48c6b392.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5667-10A (Blood Derived Normal), aliquot TCGA-A6-5667-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c28c145-9cd6-4c8b-bbf5-4bd90f157680

The open-access MAF lists 71 somatic variants for this specimen: 48 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 42, Silent 23, In Frame Del 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 135/182 reads (74%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 130/183 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV51550491; called by muse, mutect2, varscan2
- ADGRB3 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65387704; called by muse, mutect2, varscan2
- AMPH | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100343561; called by muse, mutect2
- AOX1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs778564006, COSV65980663; called by muse, mutect2, varscan2
- BBS5 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 471/1138 reads (41%) | catalogued as COSV54752222; called by muse, mutect2, varscan2
- BPHL | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 126/234 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100984567; called by muse, varscan2
- BPIFB1 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs758437993, COSV53605631, COSV53607622; called by muse, mutect2
- CCDC191 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs778514406, COSV55670023; called by muse, mutect2, varscan2
- CEP126 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142032267, COSV54826164; called by muse, mutect2, varscan2
- CHST9 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 109/164 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1291133808, COSV52432602, COSV52444029; called by muse, mutect2, varscan2
- DCPS | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55010259; called by muse, mutect2, varscan2
- DERA | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 131/273 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs778363116, COSV70773891; called by muse, mutect2, varscan2
- DMRTA1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.084); catalogued as rs775700148, COSV100364802, COSV57923910; called by muse, mutect2, varscan2
- EPHA3 | c.2717G>T p.S906I | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV60698062; called by muse, mutect2, varscan2
- FBXL18 | c.36T>A p.D12E | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66665610; called by muse, mutect2, varscan2
- IGF1R | c.627C>A p.N209K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV51273006; called by muse, mutect2, varscan2
- IL1RAPL1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 93/120 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs751673587, COSV56245277; called by muse, mutect2, varscan2
- KDM6B | c.4697G>A p.R1566H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV54679063; called by muse, mutect2, varscan2
- KNDC1 | c.4159C>T p.P1387S | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as rs1293410512, COSV58833309; called by muse, mutect2, varscan2
- LAMP2 | c.376T>C p.F126L | Missense Mutation (SNP) | VAF 114/144 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52351912; called by muse, mutect2, varscan2
- LRP2 | c.5101G>A p.V1701M | Missense Mutation (SNP) | VAF 148/351 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs757540309, COSV55545328; called by muse, mutect2, varscan2
- MED1 | c.2750A>C p.E917A | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as COSV100328151; called by muse, mutect2
- MEIS2 | c.496G>A p.E166K (on ENST00000561208 / NM_170675.5; = p.E153K on NM_002399.3) | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54932630; called by muse, mutect2, varscan2
- MTUS2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs770922189, COSV70914857; called by muse, mutect2, varscan2
- MYH13 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52822861; called by muse, mutect2, varscan2
- NCOR2 | c.4007C>T p.P1336L | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV62295266; called by muse, mutect2, varscan2
- NRIP2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61701246; called by muse, mutect2, varscan2
- PCDHGB4 | c.1418G>T p.R473M | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV53915226; called by muse, mutect2, varscan2
- PCDHGB7 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs753470433, COSV53915235; called by muse, mutect2, varscan2
- PDK2 | c.1125_1127del p.N375del | In Frame Del (DEL) | VAF 40/92 reads (43%) | catalogued as rs1460742918; called by pindel, varscan2
- PLEKHG6 | c.463A>G p.M155V | Missense Mutation (SNP) | VAF 178/378 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV50598839; called by muse, mutect2, varscan2
- PMP2 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV56266838; called by muse, mutect2, varscan2
- PRSS35 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1263494157, COSV63800270; called by muse, mutect2, varscan2
- PTPRS | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.42); catalogued as rs750655279, COSV53613591; called by muse, mutect2, varscan2
- RIMS2 | c.2045C>A p.P682Q (on ENST00000666250 / NM_001348490.2; = p.P490Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51662291; called by muse, varscan2
- RPS6KA6 | c.2064G>C p.Q688H | Missense Mutation (SNP) | VAF 93/329 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV53117502; called by muse, mutect2, varscan2
- RTL9 | c.2674C>A p.P892T | Missense Mutation (SNP) | VAF 133/177 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV71825449; called by muse, mutect2, varscan2
- SLC35E2A | n.1003G>T | Splice Region (SNP) | VAF 18/109 reads (17%) | catalogued as COSV55803094; called by muse, mutect2, varscan2
- SLC8B1 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV52526764; called by muse, mutect2, varscan2
- SYT17 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs764083934, COSV62545503; called by muse, mutect2, varscan2
- TMEM132D | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV70597984; called by muse, mutect2, varscan2
- UBE4B | c.2473C>T p.R825W (on ENST00000343090 / NM_001105562.3; = p.R696W on NM_006048.5) | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1323039408, COSV53529872; called by muse, mutect2, varscan2
- ZNF311 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV65852955; called by muse, mutect2, varscan2
- ZNF34 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 91/573 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs775635720, COSV58638525; called by muse, mutect2, varscan2
- PLXNB2 | c.2615dup p.V873Cfs*66 | Frame Shift Ins (INS) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- TTLL7 | c.694_696del p.K232del | In Frame Del (DEL) | VAF 63/135 reads (47%) | called by mutect2, pindel, varscan2
- AKR1B15 | c.159C>T p.L53= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs747847872, COSV71151272; called by muse, mutect2, varscan2
- ANO6 | c.1998A>G p.E666= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV57658214; called by muse, mutect2, varscan2
- ASTL | c.420C>T p.D140= | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as COSV100668380; called by muse, mutect2
- CALCR | c.1224C>T p.C408= (on ENST00000649521 / NM_001164737.2; = p.C392= on NM_001742.4) | Silent (SNP) | VAF 48/157 reads (31%) | catalogued as COSV64006644; called by muse, mutect2, varscan2
- COL4A1 | c.2313G>A p.A771= | Silent (SNP) | VAF 58/117 reads (50%) | catalogued as rs781701888, COSV65422895; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.8772C>A p.A2924= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as COSV55083255; called by muse, mutect2, varscan2
- CSF2RA | c.429G>A p.T143= | Silent (SNP) | VAF 200/265 reads (75%) | catalogued as rs368476257, COSV62623904; ClinVar: likely benign; called by muse, mutect2, varscan2
- ESR1 | c.987C>T p.S329= | Silent (SNP) | VAF 99/165 reads (60%) | catalogued as rs139493047, COSV52803948; called by muse, mutect2, varscan2
- GPX5 | c.354G>A p.G118= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs752625221, COSV69079197; called by muse, mutect2
- GRIN2D | c.2274C>T p.Y758= | Silent (SNP) | VAF 95/126 reads (75%) | catalogued as rs749410602, COSV53517865; ClinVar: likely benign; called by muse, mutect2, varscan2
- JMJD8 | c.789C>T p.L263= | Silent (SNP) | VAF 39/165 reads (24%) | catalogued as rs369428970, COSV99555681; called by muse, mutect2, varscan2
- KLRC2 | c.54G>A p.K18= | Silent (SNP) | VAF 145/870 reads (17%) | catalogued as rs1278038188, COSV67899566; called by mutect2, varscan2
- LRTOMT | c.138G>A p.S46= | Silent (SNP) | VAF 210/330 reads (64%) | catalogued as rs564175678, COSV53825450; called by muse, mutect2, varscan2
- MUC5B | c.2424G>T p.A808= | Silent (SNP) | VAF 40/278 reads (14%) | catalogued as rs747140553, COSV101500745, COSV71590591; called by muse, mutect2, varscan2
- MYH1 | c.816G>A p.E272= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV99876827; called by muse, mutect2
- NRAP | c.1141A>C p.R381= | Silent (SNP) | VAF 26/194 reads (13%) | catalogued as COSV63489129; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1257C>T p.L419= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV51931579; called by muse, mutect2, varscan2
- RBM14 | c.882C>T p.S294= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as COSV59558355; called by muse, mutect2, varscan2
- SGSM1 | c.1509G>A p.Q503= | Silent (SNP) | VAF 124/230 reads (54%) | catalogued as COSV101241147; called by muse, mutect2, varscan2
- SGSM2 | c.468C>T p.Y156= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs571817913, COSV52156648; called by muse, mutect2, varscan2
- SPAG16 | c.1842C>T p.D614= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as rs765928542, COSV56967112; called by muse, mutect2, varscan2
- TMCC3 | c.873G>A p.L291= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV54152858; called by muse, mutect2, varscan2
- TNN | c.3081G>A p.A1027= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs368089539; called by muse, mutect2
